Somatic mutation profile of tumor specimen MP2PRT-PAUJML-TMP1-A (aliquot MP2PRT-PAUJML-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAUJML, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,308 days).
Specimen MP2PRT-PAUJML-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fde4a96-b727-4f4f-ad43-5a0351aa4e2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJML-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJML-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e903af9b-889a-495e-97ab-82746d2d767a

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Frame Shift Del 2, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GSN | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 198/653 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs752677417, COSV57994782; called by muse, mutect2, varscan2
- SCART1 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 216/651 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs899954621, COSV62986148; called by muse, mutect2, varscan2
- ST6GAL2 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 265/594 reads (45%) | PolyPhen benign (0); catalogued as rs1188693156; called by muse, mutect2, varscan2
- CCDC93 | c.1510C>T p.L504F | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBPF1 | c.2054del p.D685Afs*175 | Frame Shift Del (DEL) | VAF 132/1433 reads (9%) | called by pindel, varscan2
- NHS | c.130A>T p.R44W | Missense Mutation (SNP) | VAF 243/934 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TRAJ6 | c.1_6delinsAA p.A2Kfs*? | Frame Shift Del (DEL) | VAF 96/447 reads (21%) | called by pindel, varscan2*
- TRDD3 | c.9_13delinsGGGACTTAGAC p.Y4delinsGLR | In Frame Ins (INS) | VAF 66/72 reads (92%) | called by pindel, varscan2*
- LHX8 | c.69C>T p.A23= | Silent (SNP) | VAF 194/386 reads (50%) | catalogued as rs1158107952; called by muse, mutect2
- PRLHR | c.138C>T p.A46= | Silent (SNP) | VAF 221/737 reads (30%) | catalogued as rs1269775744, COSV53305394; called by muse, mutect2, varscan2
- SPATA6 | c.306C>T p.D102= | Silent (SNP) | VAF 96/211 reads (45%) | catalogued as rs766541592; called by muse, mutect2, varscan2
- TRIM64 | c.867T>C p.A289= | Silent (SNP) | VAF 38/42 reads (90%) | called by mutect2, varscan2
- AC092718.9 | chr16:81149768 G>T | 5'Flank (SNP) | VAF 142/371 reads (38%) | called by muse, mutect2, varscan2
